Somatic mutation profile of tumor specimen TCGA-J7-8537-01A (aliquot TCGA-J7-8537-01A-11D-2396-08) from TCGA case TCGA-J7-8537, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 37.3 years (13,628 days).
Specimen TCGA-J7-8537-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47a8578f-5253-43c0-ad9c-44f2157125f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J7-8537-10A (Blood Derived Normal), aliquot TCGA-J7-8537-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc7c8a64-9935-4b48-bd19-fbcdcc8adb3d

The open-access MAF lists 45 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 8, Nonsense Mutation 2, Splice Site 2, Splice Region 1, In Frame Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARS2 | c.1535A>T p.D512V | Missense Mutation (SNP) | VAF 32/363 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55114568; called by muse, mutect2
- ADORA2A | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV58378813; called by muse, mutect2, varscan2
- ALDH4A1 | c.1487T>C p.V496A | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV51892223, COSV51896459; called by muse, mutect2, varscan2
- ANAPC5 | c.1256A>G p.D419G | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.412); catalogued as COSV55842592; called by muse, mutect2, varscan2
- ANAPC5 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV55841832, COSV55842606; called by muse, mutect2, varscan2
- APOB | c.3467C>T p.A1156V | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.663); catalogued as COSV51933942; called by muse, mutect2, varscan2
- ARID1A | c.6191T>C p.L2064P | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61375233, COSV61376699; called by muse, mutect2, varscan2
- CEP350 | c.5848A>T p.S1950C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV62601714; called by muse, mutect2, varscan2
- CEP95 | c.2178G>C p.Q726H | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV73609074; called by muse, mutect2, varscan2
- CSF1R | c.2844T>A p.S948R | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as COSV53834187; called by muse, mutect2, varscan2
- EIF2AK4 | c.4733A>G p.D1578G | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV51115550; called by muse, mutect2, varscan2
- EIF4A1 | c.345+2T>G p.X115_splice | Splice Site (SNP) | VAF 38/182 reads (21%) | catalogued as COSV51510639; called by muse, mutect2, varscan2
- FLG | c.10287G>T p.E3429D | Missense Mutation (SNP) | VAF 225/1209 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.754); catalogued as rs775463187, COSV64241236; called by muse, mutect2, varscan2
- GART | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 118/584 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1473155527, COSV63113773; called by muse, mutect2, varscan2
- GEN1 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58056410; called by muse, mutect2, varscan2
- GOLIM4 | c.1729A>G p.N577D | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as COSV58329516; called by muse, mutect2, varscan2
- HIVEP3 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56014611; called by muse, mutect2, varscan2
- HSPA2 | c.1852C>A p.P618T | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV55969476; called by muse, mutect2, varscan2
- IGSF10 | c.5347A>T p.N1783Y | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56784696; called by muse, mutect2, varscan2
- IL6ST | c.1612G>C p.E538Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV100411120, COSV61141045; called by muse, mutect2, varscan2
- MCF2L | c.2672A>G p.K891R (on ENST00000375608; = p.K859R on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56177236; called by muse, varscan2
- MED24 | c.1067+1G>C p.X356_splice | Splice Site (SNP) | VAF 50/333 reads (15%) | catalogued as COSV62418449; called by muse, mutect2, varscan2
- MKI67 | c.1912A>C p.I638L | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.112); catalogued as COSV64074178; called by muse, mutect2, varscan2
- NDUFAF5 | c.429A>T p.E143D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65246890; called by muse, mutect2, varscan2
- NETO2 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 73/350 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs372424394; called by muse, mutect2, varscan2
- PCDHGA1 | c.2421+5A>G | Splice Region (SNP) | VAF 33/170 reads (19%) | catalogued as COSV65296212; called by muse, mutect2, varscan2
- PUS7 | c.1840T>C p.F614L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV62676620; called by mutect2, varscan2
- RP2 | c.498C>G p.I166M | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV54461640; called by muse, mutect2, varscan2
- RYR2 | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63682810; called by muse, mutect2, varscan2
- SLITRK2 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 47/230 reads (20%) | catalogued as COSV59425066; called by muse, mutect2, varscan2
- TAS1R2 | c.1284C>A p.N428K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV64744737; called by muse, mutect2, varscan2
- VARS1 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV65151777; called by muse, mutect2, varscan2
- ZNF419 | c.1135T>G p.F379V | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.071); catalogued as COSV55659361; called by muse, mutect2, varscan2
- GRPR | c.536dup p.D180* | Frame Shift Ins (INS) | VAF 53/362 reads (15%) | called by mutect2, pindel, varscan2
- TSG101 | c.51_52del p.Y17* | Nonsense Mutation (DEL) | VAF 23/125 reads (18%) | called by mutect2, pindel, varscan2
- ZNF184 | c.1115_1117del p.T372del | In Frame Del (DEL) | VAF 16/95 reads (17%) | called by mutect2, pindel, varscan2
- CENPE | c.315T>G p.V105= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV54380612; called by muse, mutect2, varscan2
- FNBP1L | c.1257G>A p.Q419= (on ENST00000271234 / NM_001164473.2; = p.Q361= on NM_017737.5) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV53093117; called by muse, mutect2, varscan2
- LRP1B | c.4908C>T p.N1636= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs368565366; called by muse, mutect2, varscan2
- NPEPPS | c.1296A>T p.I432= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV59102280, COSV59102580; called by muse, mutect2, varscan2
- PRDM16 | c.2751C>T p.D917= | Silent (SNP) | VAF 77/299 reads (26%) | catalogued as rs1403282532, COSV54588698; called by muse, mutect2, varscan2
- ST8SIA6 | c.150G>A p.A50= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs771249416, COSV66467974; called by muse, mutect2, varscan2
- TMC7 | c.1260C>A p.I420= | Silent (SNP) | VAF 34/175 reads (19%) | catalogued as COSV58583245; called by muse, mutect2, varscan2
- TRMT9B | c.870T>C p.S290= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs1174007571, COSV71600380; called by muse, mutect2, varscan2
- UPB1 | c.364+251G>C | Intron (SNP) | VAF 11/239 reads (5%) | catalogued as COSV100387154; called by muse, mutect2
